Somatic mutation profile of tumor specimen CUPP-B38N-TTM1-A (aliquot CUPP-B38N-TTM1-A-1-0-D-A82Z-47) from CCG case CUPP-B38N, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 65.2 years (23,807 days).
Specimen CUPP-B38N-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99b91e81-9375-4e83-a130-14e5858001cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CUPP-B38N-NB1-A (Blood Derived Normal), aliquot CUPP-B38N-NB1-A-1-0-D-A82Z-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18022462-fd7b-43db-a136-fbe3a6add8d6

The open-access MAF lists 30 somatic variants for this specimen: 25 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 22, Silent 5, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1087T>C p.C363R | Missense Mutation (SNP) | VAF 18/214 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377767348, CM075017, COSV61690012, COSV61690359, COSV61695084; ClinVar: pathogenic; called by muse, mutect2
- BPIFA1 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs1205428826; called by muse, mutect2
- CTCF | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50474161; called by muse, mutect2
- HAS1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99708272; called by mutect2, varscan2
- NOTCH3 | c.5066del p.G1689Vfs*16 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as COSV54654640; called by mutect2, pindel
- PPP1R2B | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1453840682; called by muse, mutect2
- PTEN | c.513G>T p.Q171H | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV64311385; called by muse, mutect2
- ASB5 | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CYP26C1 | c.1075A>G p.S359G | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.099); called by muse, varscan2
- CYP3A4 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- DIPK1B | c.353G>C p.G118A | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FSBP | c.468A>T p.Q156H | Missense Mutation (SNP) | VAF 13/225 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.201); called by muse, mutect2
- HELZ2 | c.6317C>T p.A2106V (on ENST00000467148 / NM_001037335.2; = p.A1537V on NM_033405.3) | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- INF2 | c.221T>C p.L74P | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KCNAB2 | c.122_124del p.N41_L42delinsM | In Frame Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- LRRC47 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- MBD5 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- OR6B2 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2
- PGGHG | c.1750T>G p.F584V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- PRDM16 | c.2365C>G p.P789A | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- SERPINF2 | c.176del p.G59Afs*5 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- TAS2R46 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 17/282 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.464); called by muse, mutect2
- TEDC1 | c.1127C>A p.A376E (on ENST00000392523 / NM_001367178.1; = p.A307E on NM_001134875.1) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2
- THOC2 | c.1213A>G p.K405E | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2
- ZNF799 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.042); called by muse, mutect2
- BEST2 | c.54C>A p.S18= | Silent (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- CARMIL3 | c.3942G>A p.R1314= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- FBXW10 | c.1500C>T p.C500= | Silent (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2
- GORASP2 | c.714A>G p.S238= | Silent (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- PLXNB3 | c.2164C>T p.L722= | Silent (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2, varscan2
